CCDI case PBBWCI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other and ill-defined digestive organs.
https://portal.gdc.cancer.gov/cases/ab3c0279-6c3d-42a4-a4b2-cd976c344296

Demographics
Sex at birth: female; Race: white; Vital status: Dead.

Diagnoses (1)
1. Carcinoma, metastatic, NOS: ICD-O-3 morphology code: 8010/6; Tissue or organ of origin: Intestinal tract, NOS; Age at diagnosis: 22.7 years (8,305 days).

Biospecimens (3 samples)
- Sample 0DIW67: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIW73: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DIW84: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
